Gene-level copy-number profile of tumor specimen TCGA-YL-A8SF-01A from TCGA case TCGA-YL-A8SF, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.5 years (22,844 days).
Specimen TCGA-YL-A8SF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.f138ac7a-9881-4a60-b828-6b12c74c7ed4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YL-A8SF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/770c9bb2-e6f2-4303-8ed6-09c8906aeca0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 6,514; copy number 2: 50,371; copy number 3: 2,891.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YL-A8SF-01A-11D-A376-01): tumor purity 0.69, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:38,258,409–38,465,480, 1 gene (within-gene range 0–1): EGFLAM.
- chr5:38,345,347–38,685,126, 9 genes: EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1.
- chr8:25,820,975–27,676,776, 33 genes: AC009623.3, AC090103.1, EBF2, RNA5SP258, AC079097.1, PPP2R2A, SDAD1P1, BNIP3L, AC011726.1, DNAJB6P2, AC011726.2, PNMA2, DPYSL2, PSME2P5, ADRA1A, AC091675.1, COX6B1P4, AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35, PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,134. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
